CCDI case PBBVBA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/c6eab1f4-10a4-482a-8d36-c1a2d9ed8e03

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Neuroendocrine carcinoma, NOS: ICD-O-3 morphology code: 8246/3; Tissue or organ of origin: Lower lobe, lung; Age at diagnosis: 14.7 years (5,362 days).

Biospecimens (2 samples)
- Sample 0DJ6JZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJ6KJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
